Somatic mutation profile of tumor specimen TCGA-AA-3984-01A (aliquot TCGA-AA-3984-01A-02D-1981-10) from TCGA case TCGA-AA-3984, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.8 years (22,585 days).
Specimen TCGA-AA-3984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca206324-5775-41c6-9ac1-1073ea85be4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3984-10A (Blood Derived Normal), aliquot TCGA-AA-3984-10A-01D-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7782d47c-3790-42a3-8ac8-121f936be313

The open-access MAF lists 5,671 somatic variants for this specimen: 4,421 protein-altering or splice-affecting, 1,138 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,849, Silent 1,138, Nonsense Mutation 472, Intron 57, Splice Site 48, Splice Region 29, RNA 29, Frame Shift Ins 13, 3'UTR 12, 3'Flank 6, Nonstop Mutation 5, 5'Flank 4.

Variants (750 of 5,671; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61750065, CM990038, COSV64672644; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 55/206 reads (27%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7A | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 22/398 reads (6%) | catalogued as rs797045337, COSV100430703; ClinVar: pathogenic; called by muse, mutect2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- BRCA1 | c.4508C>A p.S1503* | Nonsense Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as rs80357437, CM062470, COSV100524045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by mutect2, varscan2
- CA8 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs387906598, CM118190, COSV58771796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by mutect2, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 39/145 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- CFTR | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 57/202 reads (28%) | catalogued as rs121909012, CM910073, COSV99135243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*2480C>T | 3'UTR (SNP) | VAF 30/121 reads (25%) | catalogued as rs375009168, CM141804, COSV99950416; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- F5 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 14/122 reads (11%) | catalogued as rs757953549, CM980661, COSV100888970; ClinVar: likely pathogenic; called by mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs754142863, CM159511, CM159512, COSV100014015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1558G>T p.D520Y (on ENST00000281708 / NM_001349798.2; = p.D440Y on NM_018315.5) | Missense Mutation (SNP) | VAF 48/176 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895090, COSV55923112, COSV55961967; called by muse, mutect2, varscan2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 68/197 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- FKTN | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 60/268 reads (22%) | catalogued as rs267606814, CM074169, COSV56312887; ClinVar: pathogenic; called by muse, varscan2
- FOXP3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs28935477, CM010059, COSV66050988; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72555358, CM910181, COSV56566787; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, mutect2, varscan2
- KCNQ1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs17215500, CM057185, CM992171; ClinVar: pathogenic / benign / uncertain significance; called by mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NMNAT1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs375110174, CM127766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853260, CM981410, COSV63980092; ClinVar: pathogenic; called by muse, varscan2
- OTX2 | c.202C>T p.R68* (on ENST00000408990 / NM_172337.3; = p.R76* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 41/126 reads (33%) | catalogued as rs773157352, COSV59766871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 14/145 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 45/568 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 50/118 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 67/252 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- PTH | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs199955107, CM1511342, COSV56378577; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RARS2 | c.419T>G p.F140C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772887102, CM162129, COSV101057238; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC37A4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193302903, CM980800, COSV100421525; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs753621591, CM121226, COSV56252267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, varscan2
- WDR72 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | catalogued as rs557128345, CM109077, COSV64751129; ClinVar: pathogenic; called by muse, varscan2
- A1CF | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as rs772118222, COSV50957228; called by muse, mutect2, varscan2
- A1CF | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs754321707, COSV99256036; called by muse, mutect2, varscan2
- A2M | c.2098C>G p.P700A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100588637; called by muse, mutect2, varscan2
- A2M | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59393078; called by muse, mutect2, varscan2
- A2ML1 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100228872; called by muse, mutect2, varscan2
- A2ML1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770246364, COSV55288421; called by muse, varscan2
- A2ML1 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100228874; called by muse, varscan2
- A2ML1 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as rs370203983; called by muse, varscan2
- A2ML1 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as COSV100228879; called by muse, varscan2
- A3GALT2 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100378166; called by muse, mutect2, varscan2
- AACS | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 143/563 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.816); catalogued as COSV99907978; called by muse, mutect2, varscan2
- AADACL3 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100206691; called by muse, mutect2, varscan2
- AARD | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1392831257, COSV100991889; called by muse, mutect2, varscan2
- AARS2 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771412; called by muse, mutect2, varscan2
- AARS2 | c.1897A>G p.T633A | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99771418; called by muse, mutect2, varscan2
- ABAT | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99190936; called by muse, mutect2, varscan2
- ABCA1 | c.6575G>A p.S2192N | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101036867, COSV66065047; called by muse, mutect2, varscan2
- ABCA1 | c.4866G>T p.E1622D | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV101036869; called by muse, mutect2, varscan2
- ABCA10 | c.2460G>T p.K820N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99288550, COSV99289532; called by muse, mutect2, varscan2
- ABCA10 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99288558; called by muse, mutect2, varscan2
- ABCA12 | c.1522A>G p.K508E (on ENST00000272895 / NM_173076.3; = p.K190E on NM_015657.3) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV99789743; called by muse, mutect2, varscan2
- ABCA13 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV101330025; called by mutect2, varscan2
- ABCA13 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101330026; called by muse, mutect2, varscan2
- ABCA13 | c.5392C>T p.L1798F | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101329919, COSV70026471; called by muse, mutect2, varscan2
- ABCA13 | c.7949A>G p.E2650G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101446929; called by muse, mutect2, varscan2
- ABCA13 | c.8255A>C p.K2752T | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV101446930; called by muse, mutect2
- ABCA13 | c.8596G>T p.E2866* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as rs551407561, COSV101446931; called by muse, mutect2, varscan2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 50/624 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2
- ABCA13 | c.14590A>C p.K4864Q | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291321; called by muse, mutect2, varscan2
- ABCA4 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64679321; called by muse, varscan2
- ABCA6 | c.3674G>T p.R1225I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52646867; called by muse, mutect2, varscan2
- ABCA6 | c.2781A>C p.Q927H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52644825, COSV99446380; called by mutect2, varscan2
- ABCA6 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52637755; called by muse, mutect2, varscan2
- ABCA6 | c.10A>C p.K4Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99446384; called by muse, mutect2, varscan2
- ABCA8 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756218261, COSV52200060; called by mutect2, varscan2
- ABCA9 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV100383068; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB7 | c.2160G>T p.W720C (on ENST00000373394 / NM_001271696.3; = p.W721C on NM_004299.6) | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV99504311; called by muse, mutect2
- ABCB7 | c.1981A>C p.I661L (on ENST00000373394 / NM_001271696.3; = p.I662L on NM_004299.6) | Missense Mutation (SNP) | VAF 56/413 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99504316; called by muse, mutect2, varscan2
- ABCB8 | c.953A>C p.K318T (on ENST00000297504 / NM_001282291.2; = p.K301T on NM_007188.5) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.292); catalogued as COSV99874315; called by muse, mutect2, varscan2
- ABCB9 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54894645; called by muse, mutect2, varscan2
- ABCC1 | c.2879T>G p.L960R | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100579449; called by muse, mutect2, varscan2
- ABCC10 | c.2212C>T p.R738C (on ENST00000372530 / NM_001198934.2; = p.R710C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016532813, COSV99767187; called by muse, mutect2, varscan2
- ABCC10 | c.4258C>T p.L1420F (on ENST00000372530 / NM_001198934.2; = p.L1392F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99767189; called by muse, mutect2, varscan2
- ABCC2 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as rs775410341, COSV64984500; called by muse, mutect2, varscan2
- ABCC2 | c.2969C>A p.S990Y | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV100966490; called by muse, mutect2, varscan2
- ABCC2 | c.3629G>A p.R1210H | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs778603543, COSV64989411; called by muse, mutect2, varscan2
- ABCC4 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs763493372, COSV65313204; called by muse, mutect2, varscan2
- ABCC5 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs778058381, COSV99656829; called by muse, mutect2, varscan2
- ABCC9 | c.4288A>G p.M1430V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99685542; called by muse, varscan2
- ABCD2 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.15); catalogued as COSV100429396; called by muse, mutect2, varscan2
- ABCD4 | c.1756C>A p.H586N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100084242, COSV53992684; called by muse, mutect2, varscan2
- ABCG1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs781254615, COSV100643048; called by muse, mutect2, varscan2
- ABCG1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs1294780786, COSV100494135; called by muse, mutect2, varscan2
- ABCG5 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs368800131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI3BP | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs199686325, COSV99426521; called by mutect2, varscan2
- ABI3BP | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs374566927; called by muse, mutect2, varscan2
- ABI3BP | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV99426525; called by muse, mutect2, varscan2
- ABI3BP | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005975720, COSV52551207; called by muse, mutect2, varscan2
- ABLIM2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315520248, COSV56408122; called by muse, mutect2, varscan2
- ABLIM2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | catalogued as COSV56404755; called by muse, mutect2
- ABLIM3 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100448327; called by muse, mutect2, varscan2
- ACACA | c.4664G>A p.R1555H | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764599804; called by muse, varscan2
- ACACB | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100622797; called by muse, mutect2, varscan2
- ACADM | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63720642; called by muse, mutect2, varscan2
- ACADSB | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100715175; called by muse, mutect2, varscan2
- ACAN | c.6166C>T p.Q2056* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100717953; called by muse, mutect2, varscan2
- ACAN | c.6693G>T p.E2231D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100717954; called by muse, mutect2, varscan2
- ACE2 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs747988885, COSV99382756; called by muse, mutect2, varscan2
- ACKR3 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56020879, COSV99799526; called by muse, mutect2, varscan2
- ACO1 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as rs376599072; called by muse, mutect2, varscan2
- ACOT12 | c.1136T>G p.I379R | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100296888; called by muse, mutect2, varscan2
- ACOT9 | c.703+2T>C p.X235_splice | Splice Site (SNP) | VAF 42/496 reads (8%) | catalogued as COSV100321259; called by muse, mutect2
- ACOX1 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99503533; called by muse, mutect2, varscan2
- ACOX3 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV100711945; called by muse, mutect2, varscan2
- ACP3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs777654881, COSV60484679; called by muse, mutect2, varscan2
- ACRBP | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs779982883, COSV99976093; called by muse, mutect2, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by muse, mutect2, varscan2
- ACSL3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62480859; called by muse, mutect2, varscan2
- ACSL4 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 100/491 reads (20%) | catalogued as COSV100538514; called by muse, mutect2, varscan2
- ACSM1 | c.192+2T>C p.X64_splice | Splice Site (SNP) | VAF 20/144 reads (14%) | catalogued as COSV99532898; called by muse, varscan2
- ACSS2 | c.1479C>A p.F493L | Missense Mutation (SNP) | VAF 133/803 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99489803; called by muse, mutect2, varscan2
- ACTBL2 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101379313; called by muse, varscan2
- ACTL7B | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.36); catalogued as COSV65927744; called by muse, mutect2, varscan2
- ACTL8 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ACTL9 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157742718, COSV61006580; called by muse, mutect2, varscan2
- ACTR1A | c.842T>G p.F281C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV100883718; called by muse, mutect2, varscan2
- ACTR1A | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100883719; called by muse, mutect2, varscan2
- ACTR3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 64/657 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs760969306, COSV54302191; called by muse, mutect2
- ACTR5 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768522307, COSV54759775; called by muse, mutect2, varscan2
- ACVR2A | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as COSV99604458; called by muse, mutect2, varscan2
- ACVR2A | c.1126A>C p.N376H | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV99604461; called by muse, mutect2, varscan2
- ADA | c.216C>T p.I72= | Splice Region (SNP) | VAF 6/61 reads (10%) | catalogued as rs769218320, COSV100866597; called by mutect2, varscan2
- ADA2 | c.1203G>T p.K401N (on ENST00000262607; = p.K160N on NM_177405.3) | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV99375995; called by muse, mutect2, varscan2
- ADAM17 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs756129840, COSV100176225; called by muse, mutect2, varscan2
- ADAM19 | c.1067A>C p.D356A | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977012; called by muse, mutect2, varscan2
- ADAM2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV99697267; called by muse, mutect2
- ADAM28 | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99738553; called by muse, mutect2, varscan2
- ADAM33 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100597856; called by muse, mutect2, varscan2
- ADAM7 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51538749; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.691); catalogued as rs1323137106, COSV99836038; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV99836039; called by muse, mutect2, varscan2
- ADAMTS1 | c.2509A>G p.K837E | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV99536073; called by muse, varscan2
- ADAMTS1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53168803; called by muse, varscan2
- ADAMTS12 | c.2283G>A p.W761* | Nonsense Mutation (SNP) | VAF 72/214 reads (34%) | catalogued as COSV100710810; called by muse, varscan2
- ADAMTS12 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV100710811, COSV61264418; called by muse, mutect2, varscan2
- ADAMTS16 | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99940998; called by muse, mutect2, varscan2
- ADAMTS16 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754871314, COSV56977587; called by muse, mutect2
- ADAMTS17 | c.2467A>G p.T823A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.277); catalogued as COSV99170599; called by muse, mutect2, varscan2
- ADAMTS19 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99177466; called by muse, mutect2
- ADAMTS2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771509811, COSV51075719; called by mutect2, varscan2
- ADAMTS20 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV67134539; called by muse, varscan2
- ADAMTS3 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs759103275, COSV54387946, COSV99710963; called by mutect2, varscan2
- ADAMTS8 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs749975173, COSV99960877; called by muse, mutect2, varscan2
- ADAMTS8 | c.1953A>C p.E651D | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99960879; called by muse, mutect2, varscan2
- ADAMTSL1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs200648653, COSV99442517; called by muse, varscan2
- ADAMTSL3 | c.4477T>G p.S1493A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99718600; called by muse, varscan2
- ADAMTSL4 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs149442347; called by muse, mutect2, varscan2
- ADAP2 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100437237; called by muse, mutect2, varscan2
- ADCY4 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV60252904; called by muse, varscan2
- ADCY5 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs775356872, COSV100567636, COSV59201837; called by muse, mutect2, varscan2
- ADD1 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV99296391; called by muse, mutect2, varscan2
- ADD2 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV52473422; called by muse, mutect2, varscan2
- ADGRA3 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs928853508, COSV51561936; called by muse, mutect2, varscan2
- ADGRB1 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.359); catalogued as COSV100029589; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2
- ADGRB3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV65384210; called by muse, mutect2, varscan2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, varscan2
- ADGRB3 | c.3259T>G p.L1087V | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as COSV99484899; called by muse, varscan2
- ADGRD1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1190105071, COSV55458534; called by muse, mutect2, varscan2
- ADGRD1 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs756810149, COSV55442677; called by muse, mutect2, varscan2
- ADGRE2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs754889485, COSV59693104; called by muse, mutect2, varscan2
- ADGRF5 | c.1833T>G p.A611= | Splice Region (SNP) | VAF 24/138 reads (17%) | catalogued as COSV99345508; called by muse, mutect2, varscan2
- ADGRG4 | c.3760T>G p.L1254V | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99795334; called by muse, varscan2
- ADGRG4 | c.3769G>A p.D1257N | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.569); catalogued as rs762948773, COSV99795335; called by muse, varscan2
- ADGRG6 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1271357229, COSV51598215, COSV99746936; called by muse, mutect2, varscan2
- ADGRG7 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as COSV99840959; called by muse, mutect2, varscan2
- ADGRL2 | c.3095A>G p.N1032S (on ENST00000370717 / NM_001366005.1; = p.N1019S on NM_012302.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as COSV99588792; called by mutect2, varscan2
- ADGRL2 | c.3379C>T p.R1127C (on ENST00000370717 / NM_001366005.1; = p.R1114C on NM_012302.4) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775087345, COSV54673990, COSV54685771; called by muse, varscan2
- ADGRL3 | c.696G>T p.Q232H (on ENST00000506720 / NM_001322402.2; = p.Q164H on NM_015236.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101547082; called by muse, mutect2, varscan2
- ADGRV1 | c.6590T>G p.L2197R | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101315823, COSV67980076; called by muse, mutect2, varscan2
- ADGRV1 | c.7292C>T p.A2431V | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101315824; called by muse, mutect2, varscan2
- ADGRV1 | c.10300T>G p.L3434V | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); catalogued as COSV101315825; called by muse, mutect2, varscan2
- ADGRV1 | c.15325T>C p.W5109R | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101315826; called by muse, mutect2, varscan2
- ADGRV1 | c.16693A>G p.T5565A | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV101315827; called by muse, mutect2, varscan2
- ADH1A | c.345C>T p.N115= | Splice Region (SNP) | VAF 28/410 reads (7%) | catalogued as rs1412779396, COSV52926005; called by muse, mutect2
- ADH1C | c.225A>C p.E75D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV101565179, COSV101565202, COSV72463662; called by muse, mutect2, varscan2
- ADH6 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52954963, COSV99422264; called by muse, mutect2, varscan2
- ADNP | c.1889T>C p.I630T | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.506); catalogued as COSV100823726; called by muse, mutect2, varscan2
- ADNP | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 89/375 reads (24%) | catalogued as COSV100823727; called by muse, mutect2, varscan2
- ADPRM | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101126063; called by muse, mutect2
- ADRA1D | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1169227367, COSV65240700; called by muse, mutect2
- ADRB1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100992278; called by muse, mutect2, varscan2
- AEBP1 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99788745; called by muse, mutect2, varscan2
- AEN | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100237425; called by muse, mutect2, varscan2
- AFF4 | c.2281T>G p.S761A | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.176); catalogued as COSV99534881; called by muse, mutect2, varscan2
- AFG1L | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs778941841, COSV100933937; called by mutect2, varscan2
- AFG1L | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV100933938; called by muse, mutect2
- AFG3L2 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as rs754307169, COSV99301835; called by muse, mutect2, varscan2
- AFTPH | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | catalogued as COSV99480635; called by muse, mutect2, varscan2
- AFTPH | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.347); catalogued as COSV99480641; called by muse, mutect2, varscan2
- AGAP3 | c.2036G>A p.R679H (on ENST00000622464; = p.R715H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750679955, COSV68244885; called by muse, mutect2, varscan2
- AGL | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 53/177 reads (30%) | catalogued as COSV54049072, COSV54059254, COSV99648854; called by muse, mutect2, varscan2
- AGO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs748561732, COSV64594648; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 59/184 reads (32%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGTR2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs782176432, COSV64156534, COSV64157083; called by muse, mutect2
- AGXT2 | c.1532G>T p.R511I | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99183744; called by muse, mutect2, varscan2
- AGXT2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs756036796, COSV51487388; called by muse, varscan2
- AGXT2 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV51490389; called by muse, varscan2
- AHCYL1 | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV63208905; called by muse, mutect2
- AHI1 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662612; called by muse, mutect2
- AHNAK2 | c.3938A>G p.D1313G | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100317340, COSV60916656; called by muse, mutect2, varscan2
- AHNAK2 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | catalogued as rs1188646569, COSV60912557; called by muse, mutect2, varscan2
- AICDA | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV57564989; called by muse, mutect2, varscan2
- AJAP1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.124); catalogued as rs764507777, COSV100981669; called by muse, varscan2
- AKAP11 | c.4399A>C p.K1467Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99213854; called by muse, mutect2, varscan2
- AKAP13 | c.1782A>C p.K594N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100773688; called by mutect2, varscan2
- AKAP6 | c.5030C>T p.A1677V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99800473; called by muse, mutect2, varscan2
- AKAP6 | c.5684A>G p.E1895G | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99800479; called by muse, mutect2, varscan2
- AKAP9 | c.10000C>T p.R3334W (on ENST00000359028; = p.R3310W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs779243745, COSV62337823; called by muse, mutect2, varscan2
- AKIRIN2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57636871; called by muse, mutect2
- AKNA | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs746973445, COSV99800235; called by muse, mutect2, varscan2
- AKNA | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99800239; called by muse, mutect2
- AKR1B1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs770279911, COSV53648323; called by muse, mutect2, varscan2
- AKR1C4 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs529198618, COSV54125324; called by muse, mutect2, varscan2
- AKT2 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 47/164 reads (29%) | catalogued as COSV100251588; called by muse, mutect2, varscan2
- AKT2 | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100251589; called by muse, varscan2
- AL035461.3 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs771270190, COSV66652084; called by muse, varscan2
- AL035461.3 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 64/243 reads (26%) | catalogued as rs145778654; called by muse, varscan2
- AL121899.2 | c.1706A>C p.E569A | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101198438; called by muse, mutect2, varscan2
- AL121899.2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1205086132, COSV67352495; called by muse, mutect2
- ALAD | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs973089315, COSV99474730; called by muse, mutect2, varscan2
- ALAS2 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as COSV100238231; called by muse, mutect2
- ALAS2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100238233; called by muse, mutect2
- ALB | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV99891382; called by muse, mutect2, varscan2
- ALDH1A3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs371736673; called by muse, mutect2, varscan2
- ALDH1L1 | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99856761; called by muse, mutect2, varscan2
- ALDH3A2 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99449849; called by muse, mutect2, varscan2
- ALDH3B1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780821654, COSV99141861; called by muse, mutect2, varscan2
- ALDH8A1 | c.51A>C p.K17N | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99664681; called by muse, mutect2
- ALG10B | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 56/776 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV100439884; called by muse, mutect2
- ALG11 | c.1294G>C p.G432R | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV101584275; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 52/252 reads (21%) | catalogued as COSV52634896; called by mutect2, varscan2
- ALG5 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs544999445, COSV53507460; called by muse, mutect2, varscan2
- ALG8 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 136/510 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55203092; called by muse, mutect2, varscan2
- ALKBH8 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV99508427, COSV99508661; called by muse, mutect2, varscan2
- ALLC | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as rs371999138, COSV52997740; called by muse, mutect2, varscan2
- ALMS1 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs746391155, COSV52506333; called by muse, varscan2
- ALMS1 | c.11885T>G p.F3962C | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042268; called by muse, mutect2, varscan2
- ALOX12B | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1064796312, COSV59871687; called by muse, mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ALOXE3 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as COSV59074205; called by muse, mutect2, varscan2
- ALPI | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151137290; called by muse, mutect2, varscan2
- ALPK2 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100864326; called by muse, mutect2, varscan2
- ALPK3 | c.4694A>C p.N1565T | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99360788; called by muse, mutect2, varscan2
- ALS2 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1309144602, COSV51887988; called by muse, mutect2, varscan2
- ALS2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs762706628, COSV99969233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBN | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827212; called by muse, mutect2, varscan2
- AMBRA1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV54049679; called by muse, mutect2, varscan2
- AMDHD1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV99900295; called by muse, mutect2, varscan2
- AMDHD1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 54/375 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338270376, COSV99900297; called by muse, mutect2, varscan2
- AMER1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100365980; called by muse, mutect2, varscan2
- AMER2 | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100766234; called by muse, mutect2, varscan2
- AMER3 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs756210400, COSV100366172, COSV58465910; called by muse, mutect2, varscan2
- AMMECR1 | c.548A>C p.N183T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV99466657; called by muse, mutect2
- AMPD1 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142643298; called by muse, mutect2, varscan2
- AMPD1 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100815014; called by muse, mutect2, varscan2
- AMPD1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs140601541, COSV100814850; called by mutect2, varscan2
- AMZ1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs749021540, COSV100406368; called by muse, mutect2, varscan2
- AMZ2 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100703148; called by muse, mutect2, varscan2
- ANG | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs141398857, CM1110462, COSV100390908; called by muse, mutect2, varscan2
- ANGPTL5 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs766108959, COSV57532892; called by mutect2, varscan2
- ANGPTL5 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57531879, COSV57534940; called by muse, mutect2, varscan2
- ANGPTL5 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.684); catalogued as COSV100527768, COSV57533138; called by muse, mutect2, varscan2
- ANK3 | c.8352T>G p.F2784L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99779694; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 149/453 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANKAR | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 21/208 reads (10%) | catalogued as COSV99854172, COSV99854192; called by muse, mutect2, varscan2
- ANKAR | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV99854175; called by muse, mutect2, varscan2
- ANKEF1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs145101692; called by muse, mutect2, varscan2
- ANKFN1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV100593419; called by muse, mutect2, varscan2
- ANKH | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99414939, COSV99415545; called by muse, mutect2, varscan2
- ANKH | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1440219037, COSV99414941; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5365C>A p.H1789N | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.037); catalogued as COSV51859567, COSV99783151; called by muse, mutect2, varscan2
- ANKIB1 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as COSV99728962; called by muse, varscan2
- ANKK1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.262); catalogued as rs762261977, COSV58274315; called by muse, mutect2, varscan2
- ANKK1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs369229013; called by muse, mutect2, varscan2
- ANKRA2 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99707010; called by muse, mutect2, varscan2
- ANKRD11 | c.2518C>T p.R840W | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761259443, CD162073, COSV56363768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs371617857, COSV100041204; called by muse, mutect2, varscan2
- ANKRD13A | c.1429A>T p.N477Y | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV99923957; called by muse, mutect2
- ANKRD13C | c.1497T>C p.D499= | Splice Region (SNP) | VAF 29/109 reads (27%) | catalogued as COSV99256764; called by muse, mutect2, varscan2
- ANKRD28 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV101080605; called by muse, mutect2, varscan2
- ANKRD33 | c.355C>T p.R119W (on ENST00000340970 / NM_001304459.2; = p.R244W on NM_182608.4) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764706850, COSV56605673; called by muse, mutect2
- ANKRD35 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100841714; called by muse, mutect2, varscan2
- ANKRD44 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs780836038, COSV99984889; called by mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- ANKRD44 | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV56553501, COSV99984894; called by muse, mutect2, varscan2
- ANKRD46 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 154/396 reads (39%) | catalogued as rs1480467503, COSV100170018; called by muse, mutect2, varscan2
- ANKRD6 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1485147328, COSV100329815; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- ANKS1B | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245245; called by muse, mutect2, varscan2
- ANKS6 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100782263; called by muse, mutect2, varscan2
- ANLN | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774828191, COSV99732220; called by muse, mutect2, varscan2
- ANLN | c.1696A>C p.N566H | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99732222; called by muse, mutect2
- ANLN | c.3356A>C p.K1119T | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99732223; called by muse, mutect2, varscan2
- ANO2 | c.1955A>G p.Y652C (on ENST00000356134 / NM_001278597.3; = p.Y656C on NM_001278596.3) | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310218589, COSV100500745; called by muse, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ANO3 | c.2446C>A p.L816I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882507; called by muse, mutect2, varscan2
- ANO4 | c.338G>A p.R113Q (on ENST00000392977 / NM_001286615.2; = p.R78Q on NM_178826.4) | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1442015501, COSV100152777, COSV54606721; called by muse, mutect2, varscan2
- ANO6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs747156509, COSV100263073; called by muse, mutect2, varscan2
- ANO6 | c.2632C>A p.L878I | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as COSV100263087; called by muse, mutect2, varscan2
- ANOS1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761052947, COSV99390839; called by muse, mutect2, varscan2
- ANP32E | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs143260001; called by muse, mutect2, varscan2
- ANXA11 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV99627080; called by muse, mutect2, varscan2
- ANXA13 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99146096; called by muse, mutect2, varscan2
- AOAH | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51738460; called by muse, mutect2, varscan2
- AOC2 | c.1730G>T p.S577I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV99520035; called by mutect2, varscan2
- AP1G1 | c.539A>C p.K180T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100250385; called by muse, mutect2, varscan2
- AP1G2 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1157308575, COSV55337484; called by muse, mutect2
- AP3B2 | c.3160A>G p.T1054A (on ENST00000261722; = p.T1048A on NM_004644.5) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99916445; called by muse, mutect2, varscan2
- AP3M2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441532; called by muse, mutect2, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by muse, mutect2, varscan2
- APBA2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV67104459; called by muse, mutect2, varscan2
- APBA2 | c.2232G>T p.E744D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV99721829; called by muse, mutect2, varscan2
- APBB3 | c.538A>C p.S180R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV100021286; called by muse, mutect2, varscan2
- APC | c.8351T>G p.F2784C | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967584; called by muse, mutect2, varscan2
- APC2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1483386944, COSV99279385; called by muse, varscan2
- APCDD1L | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs147147447; called by mutect2, varscan2
- APEH | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs767157178, COSV99608297; called by muse, mutect2, varscan2
- APLP2 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs773309208, COSV99599671; called by mutect2, varscan2
- APOB | c.11687C>T p.A3896V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as rs759708973, COSV51931713; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOB | c.4410T>G p.H1470Q | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99265399; called by muse, mutect2, varscan2
- APOBEC2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs748645869, COSV55142717; called by muse, mutect2, varscan2
- APOBEC3G | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs531397529, COSV101349069; called by muse, varscan2
- APOC4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1331127938, COSV52990344, COSV99376950; called by muse, mutect2, varscan2
- AQR | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs980589387, COSV50054153; called by muse, mutect2, varscan2
- ARAP2 | c.1882A>C p.T628P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100394571; called by muse, mutect2, varscan2
- ARAP2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs551766032, COSV58290634; called by mutect2, varscan2
- ARF1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV99683167; called by muse, mutect2, varscan2
- ARF4 | c.293A>C p.E98A | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV100327170; called by muse, mutect2, varscan2
- ARFGEF1 | c.4894G>A p.D1632N | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs773060622, COSV51602227; called by muse, mutect2, varscan2
- ARFGEF1 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 110/231 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99142173; called by mutect2, varscan2
- ARFGEF2 | c.4760A>G p.D1587G | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV100904234; called by muse, mutect2, varscan2
- ARFIP2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV99601502; called by muse, mutect2, varscan2
- ARHGAP10 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776974905, COSV100331201, COSV60599477; called by muse, mutect2, varscan2
- ARHGAP11A | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 39/168 reads (23%) | catalogued as rs776172390, COSV64380835; called by muse, varscan2
- ARHGAP21 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100256124; called by muse, mutect2
- ARHGAP26 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99190858; called by muse, mutect2, varscan2
- ARHGAP28 | c.614T>G p.V205G (on ENST00000383472 / NM_001366230.1; = p.V46G on NM_001010000.3) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV99150208; called by muse, mutect2, varscan2
- ARHGAP32 | c.2933A>G p.D978G (on ENST00000310343 / NM_001378025.1; = p.D629G on NM_014715.4) | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs765032782, COSV100087697; called by muse, mutect2
- ARHGAP33 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs1314581741, COSV99138114; called by muse, mutect2, varscan2
- ARHGAP35 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs564899532, COSV68333501; called by muse, mutect2, varscan2
- ARHGAP4 | c.1534T>G p.F512V | Missense Mutation (SNP) | VAF 96/400 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100604020; called by muse, varscan2
- ARHGAP9 | c.1706G>T p.R569I (on ENST00000393797 / NM_001319850.2; = p.R550I on NM_032496.4) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57360740, COSV99954074; called by muse, mutect2, varscan2
- ARHGEF11 | c.2554C>T p.R852* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100168539; called by muse, mutect2, varscan2
- ARHGEF2 | c.548G>A p.R183Q (on ENST00000361247 / NM_001162383.2; = p.R156Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV100560521; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF26 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 51/308 reads (17%) | catalogued as COSV100726538; called by muse, mutect2, varscan2
- ARHGEF28 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777295435, COSV99708944; called by muse, mutect2, varscan2
- ARHGEF28 | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364305361, COSV99708947; called by muse, mutect2, varscan2
- ARHGEF5 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99282798; called by muse, mutect2, varscan2
- ARHGEF6 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 49/318 reads (15%) | catalogued as COSV99166443; called by muse, mutect2, varscan2
- ARHGEF6 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV51689074; called by muse, mutect2, varscan2
- ARHGEF6 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166445; called by muse, mutect2, varscan2
- ARHGEF9 | c.1111T>G p.Y371D | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV99491712; called by muse, mutect2, varscan2
- ARID1A | c.2999C>A p.S1000Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61376095, COSV61380392, COSV61383336; called by muse, mutect2, varscan2
- ARID1B | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs774777278, COSV99268860; called by muse, mutect2, varscan2
- ARID1B | c.5819G>A p.R1940H | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684987; called by muse, mutect2, varscan2
- ARID3C | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100965858; called by muse, mutect2
- ARID4B | c.3263C>T p.S1088L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs768130451, COSV99935545; called by muse, mutect2, varscan2
- ARL5A | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 58/243 reads (24%) | catalogued as COSV99706604; called by muse, varscan2
- ARMC12 | c.493G>A p.E165K (on ENST00000373866 / NM_001286574.2; = p.E192K on NM_145028.5) | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99849453; called by muse, mutect2, varscan2
- ARMC2 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV100933539; called by muse, mutect2
- ARMC8 | c.65G>A p.R22H (on ENST00000469044 / NM_001363941.2; = p.R8H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61767707; called by muse, mutect2, varscan2
- ARMC8 | c.549T>G p.I183M (on ENST00000469044 / NM_001363941.2; = p.I169M on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV100627626; called by muse, mutect2, varscan2
- ARMCX1 | c.1115A>C p.E372A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV100863187; called by muse, mutect2, varscan2
- ARMCX2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV57529321, COSV57529549; called by muse, mutect2, varscan2
- ARMH3 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64238719; called by muse, varscan2
- ARMT1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100939784; called by muse, mutect2, varscan2
- ARNT2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57591420; called by muse, mutect2, varscan2
- ARNTL | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100724710, COSV62985616; called by muse, mutect2, varscan2
- ARNTL2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs780181750, COSV53826353; called by mutect2, varscan2
- ARNTL2 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV99667719; called by muse, varscan2
- ARPC3 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99959515; called by mutect2, varscan2
- ARPP21 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV99491862; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, mutect2, varscan2
- ARR3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 445/989 reads (45%) | catalogued as rs1192044232, COSV57204706; called by muse, mutect2, varscan2
- ARR3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV99333645; called by muse, mutect2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by muse, mutect2, varscan2
- ARSB | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV53727318, COSV99364688; called by muse, mutect2, varscan2
- ARSH | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101139825; called by muse, mutect2
- ARSH | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 94/516 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101139826; called by muse, varscan2
- AS3MT | c.383A>C p.N128T | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100185690; called by muse, varscan2
- AS3MT | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756960577, COSV100185691; called by muse, varscan2
- ASAP2 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.665); catalogued as rs1139804, COSV99856134; called by muse, mutect2, varscan2
- ASAP3 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV100369402; called by muse, mutect2, varscan2
- ASB15 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1173908012, COSV99306481; called by muse, varscan2
- ASB15 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306486; called by muse, mutect2, varscan2
- ASB9 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 172/354 reads (49%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV100995476; called by muse, mutect2, varscan2
- ASCC3 | c.4409T>C p.V1470A | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64978623; called by muse, mutect2, varscan2
- ASCC3 | c.3590G>A p.R1197Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1375395896, COSV100225375; called by muse, mutect2, varscan2
- ASCC3 | c.1758A>C p.E586D | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225661; called by muse, mutect2, varscan2
- ASCL1 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901895, COSV99901983; called by muse, mutect2, varscan2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASIC2 | c.1362T>G p.I454M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV56769289, COSV99859986; called by muse, mutect2, varscan2
- ASIC2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs754954730, COSV100726304; called by muse, mutect2, varscan2
- ASIC3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs745324943, COSV52521259; called by muse, mutect2, varscan2
- ASIC5 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101611130; called by muse, mutect2, varscan2
- ASMT | c.931G>T p.E311* (on ENST00000381229; = p.E339* on NM_004043.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 49/587 reads (8%) | catalogued as COSV101172450; called by muse, mutect2
- ASMTL | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs200707318, COSV101187745; called by muse, mutect2, varscan2
- ASNSD1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs753403228, COSV53623167, COSV99641395; called by muse, mutect2, varscan2
- ASPM | c.6995G>A p.R2332Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.183); catalogued as rs758752317, COSV54142558; called by mutect2, varscan2
- ASPM | c.5009T>C p.V1670A | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV99660219; called by muse, mutect2, varscan2
- ASPM | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1215927812, COSV54132233, COSV99660220; called by muse, mutect2, varscan2
- ASPM | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV99660221; called by muse, mutect2, varscan2
- ASPRV1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs747852584, COSV57228976; called by mutect2, varscan2
- ASTN1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs377210940, COSV56061502; called by muse, mutect2, varscan2
- ATAD2 | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 26/335 reads (8%) | catalogued as COSV99784605; called by muse, mutect2
- ATAD5 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100429925; called by muse, mutect2, varscan2
- ATF1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs763994606, COSV50394055; called by muse, mutect2, varscan2
- ATF7 | c.1306G>A p.A436T (on ENST00000548446 / NM_001366555.2; = p.A425T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100129400; called by muse, mutect2, varscan2
- ATG2B | c.3790A>G p.T1264A | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99952031; called by muse, mutect2, varscan2
- ATG9A | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100036924; called by muse, mutect2, varscan2
- ATM | c.897A>C p.E299D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99589425; called by muse, mutect2
- ATM | c.6641A>G p.D2214G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99589428; called by muse, mutect2, varscan2
- ATM | c.7793G>A p.R2598Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140263969, CX030370; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP10D | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99905559; called by mutect2, varscan2
- ATP11B | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1218452517, COSV60026567; called by mutect2, varscan2
- ATP11B | c.2195T>G p.L732R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017737; called by muse, mutect2, varscan2
- ATP11C | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 156/755 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1033024084, COSV59559449, COSV59565145; called by muse, varscan2
- ATP11C | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 58/661 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV100557809; called by muse, mutect2
- ATP13A1 | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762823776, COSV99179219; called by muse, mutect2, varscan2
- ATP1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759097524, COSV100767806, COSV100768062; called by muse, mutect2
- ATP1A3 | c.2607C>A p.F869L (on ENST00000545399 / NM_001256214.2; = p.F856L on NM_152296.5) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV57491436; called by muse, mutect2, varscan2
- ATP1A4 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as rs376262146, COSV63626819; called by muse, mutect2, varscan2
- ATP2B3 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs782034545, COSV54856756; called by muse, mutect2
- ATP2B3 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs782080544, COSV54859713; called by muse, mutect2, varscan2
- ATP2B4 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100397440; called by muse, mutect2, varscan2
- ATP2C2 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs780004695, COSV99297988; called by mutect2, varscan2
- ATP5MPL | c.150T>G p.A50= | Splice Region (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99743857, COSV99744017; called by mutect2, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V1A | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99850088; called by muse, mutect2, varscan2
- ATP6V1B1 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV99314057; called by muse, mutect2, varscan2
- ATP7B | c.4189G>A p.A1397T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1220392640, COSV99666388; called by muse, mutect2, varscan2
- ATP8A2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99681663; called by muse, mutect2, varscan2
- ATP8A2 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99681664, COSV99682258; called by muse, mutect2, varscan2
- ATP8B1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 55/195 reads (28%) | catalogued as COSV52173638; called by muse, mutect2, varscan2
- ATP8B4 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52723464; called by muse, mutect2, varscan2
- ATP9B | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140291894, COSV56956164; called by muse, varscan2
- ATR | c.3181G>T p.E1061* | Nonsense Mutation (SNP) | VAF 33/142 reads (23%) | catalogued as COSV100638173, COSV63390295; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, varscan2
- ATRNL1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100745224; called by muse, mutect2, varscan2
- ATRNL1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as rs1554924686, COSV58114600; called by muse, mutect2
- ATXN1 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV99786218; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- ATXN7 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99894310; called by muse, mutect2, varscan2
- ATXN7L1 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.758); catalogued as COSV100596839; called by muse, mutect2, varscan2
- AURKC | c.773T>G p.F258C (on ENST00000302804 / NM_001015878.2; = p.F224C on NM_003160.3) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV100248829; called by muse, mutect2, varscan2
- AVPR2 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV100509499; called by muse, mutect2, varscan2
- AXDND1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as COSV62647920; called by muse, mutect2, varscan2
- B3GALT2 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100813590; called by muse, mutect2, varscan2
- B3GNT2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57345901; called by muse, mutect2, varscan2
- B3GNT7 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55007800; called by muse, mutect2, varscan2
- B4GALT3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100157712; called by muse, mutect2, varscan2
- BACH1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54518055; called by muse, mutect2, varscan2
- BACH2 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV57611253, COSV99999223; called by muse, varscan2
- BAG3 | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV100958223; called by muse, mutect2, varscan2
- BAHCC1 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 66/191 reads (35%) | catalogued as COSV100311568; called by muse, mutect2, varscan2
- BAMBI | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.978); catalogued as COSV100977498; called by muse, mutect2
- BANK1 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536273; called by muse, mutect2, varscan2
- BANK1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100536274; called by muse, mutect2, varscan2
- BANP | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1363604275, COSV53745462; called by muse, mutect2
- BAZ1B | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 28/286 reads (10%) | catalogued as COSV100289720; called by muse, mutect2
- BBOF1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs759690523, COSV101223845; called by muse, mutect2, varscan2
- BBS2 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs761068592, COSV55326240; called by muse, mutect2, varscan2
- BBS2 | c.720G>A p.S240= | Splice Region (SNP) | VAF 10/82 reads (12%) | catalogued as rs758715963, COSV99802370; called by mutect2, varscan2
- BBS9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs541526329, COSV54169144; called by muse, mutect2, varscan2
- BBS9 | c.2273C>T p.P758L (on ENST00000242067 / NM_001348036.1; = p.P718L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757754301, COSV54165316, COSV54173388; called by mutect2, varscan2
- BBX | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100361478, COSV100362249; called by muse, mutect2, varscan2
- BCL10 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV100997795, COSV65353814; called by muse, mutect2, varscan2
- BCL11A | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100185558; called by muse, mutect2, varscan2
- BCL9 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs782091140, COSV52342408; called by muse, mutect2, varscan2
- BCOR | c.3734C>T p.A1245V (on ENST00000378444 / NM_001123385.2; = p.A1211V on NM_017745.6) | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100653250; called by muse, mutect2
- BDP1 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 56/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100703010; called by muse, mutect2
- BDP1 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1387255387, COSV62432953; called by muse, mutect2, varscan2
- BEND2 | c.2168A>C p.K723T | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV101191972, COSV66215845; called by muse, mutect2, varscan2
- BEND2 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 194/460 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752043959, COSV66216785; called by muse, mutect2, varscan2
- BEND2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101191976; called by muse, mutect2, varscan2
- BEX1 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101022484; called by muse, mutect2, varscan2
- BFSP1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746995142, COSV64899273; called by muse, mutect2, varscan2
- BHMT2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 55/240 reads (23%) | catalogued as COSV54872301, COSV54874260; called by muse, mutect2, varscan2
- BICC1 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765378631, COSV99570484; called by muse, mutect2, varscan2
- BICD1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV55689476; called by muse, mutect2, varscan2
- BICD1 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.391); catalogued as COSV99862358; called by muse, mutect2, varscan2
- BIRC6 | c.2456A>C p.N819T | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101428236; called by muse, mutect2
- BIRC6 | c.3347A>C p.N1116T | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV101428237, COSV70206385; called by muse, mutect2, varscan2
- BIRC6 | c.5146G>A p.V1716I | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV101428238; called by muse, mutect2, varscan2
- BIRC6 | c.5366G>T p.R1789I | Missense Mutation (SNP) | VAF 170/477 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70196149; called by muse, mutect2, varscan2
- BIRC6 | c.8734G>A p.E2912K | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs1448733090, COSV70201673, COSV70201836; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.521A>C p.K174T | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1209063590, COSV99958721; called by muse, mutect2, varscan2
- BLZF1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV61393075; called by muse, mutect2, varscan2
- BLZF1 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100250593; called by muse, mutect2, varscan2
- BMP15 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140319105, COSV99399328, COSV99399360; called by muse, mutect2
- BMP2K | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 43/164 reads (26%) | catalogued as COSV100621693; called by muse, mutect2, varscan2
- BMP3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99261621, COSV99262050; called by muse, mutect2, varscan2
- BMPR1B | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.315); catalogued as COSV99215788; called by muse, mutect2, varscan2
- BMPR1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215792; called by muse, mutect2, varscan2
- BMPR2 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.805); catalogued as rs137852752, CM053137; called by mutect2, varscan2
- BMS1 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs753613781, COSV100996686; called by muse, mutect2, varscan2
- BMS1 | c.2212C>A p.L738I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as COSV100996688; called by muse, mutect2
- BNC1 | c.2346A>C p.E782D | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100597155; called by muse, mutect2, varscan2
- BNC2 | c.3222T>G p.F1074L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101035930; called by muse, mutect2, varscan2
- BNC2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.096); catalogued as rs1287921241, COSV66147986; called by muse, mutect2, varscan2
- BNIP1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776652848, COSV51571239; called by muse, mutect2, varscan2
- BOC | c.3080C>A p.A1027D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV99848615; called by muse, mutect2, varscan2
- BOD1L1 | c.1767G>T p.K589N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99239238; called by muse, mutect2
- BOD1L1 | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99239240; called by muse, mutect2, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- BPI | c.848G>A p.R283H (on ENST00000262865; = p.R279H on NM_001725.3) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs183269384; called by muse, mutect2, varscan2
- BPIFA1 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100845638; called by muse, varscan2
- BPIFC | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs369618463, COSV100300744, COSV100301024; called by muse, mutect2, varscan2
- BPTF | c.3952A>C p.K1318Q | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100074802; called by muse, mutect2, varscan2
- BRAP | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 258/1126 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100554112; called by muse, mutect2, varscan2
- BRCA1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs80356994, CM1211132; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- BRCC3 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 114/510 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.42); catalogued as COSV100341581; called by muse, varscan2
- BRD1 | c.2987G>T p.R996I (on ENST00000216267 / NM_001349940.1; = p.R1127I on NM_001304808.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99349686; called by mutect2, varscan2
- BRD2 | c.2271G>A p.A757= | Splice Region (SNP) | VAF 15/64 reads (23%) | catalogued as rs199954603, COSV100875660; called by muse, mutect2, varscan2
- BRDT | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as COSV100746342, COSV62867386; called by muse, mutect2, varscan2
- BRDT | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV62867987; called by muse, mutect2, varscan2
- BRIP1 | c.3213A>T p.E1071D | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.693); catalogued as COSV99369980; called by muse, mutect2, varscan2
- BRIP1 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369983; called by muse, mutect2, varscan2
- BRMS1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs768620232, COSV100240228, COSV100240244; called by muse, mutect2, varscan2
- BRPF3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160592236, COSV60207201; called by muse, mutect2, varscan2
- BRWD3 | c.5302T>G p.F1768V | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV64746189; called by muse, varscan2
- BRWD3 | c.5236C>T p.R1746* | Nonsense Mutation (SNP) | VAF 159/357 reads (45%) | catalogued as rs868344048, COSV100955976; ClinVar: uncertain significance; called by muse, varscan2
- BRWD3 | c.4988G>T p.R1663I | Missense Mutation (SNP) | VAF 343/742 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV64745986; called by muse, mutect2, varscan2
- BRWD3 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs867108306, COSV100956282, COSV64747596; called by muse, mutect2, varscan2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 56/433 reads (13%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2, varscan2
- BRWD3 | c.1682A>C p.Y561S | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100955980, COSV64749133; called by muse, mutect2, varscan2
- BSN | c.5092C>A p.L1698I | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV56512845, COSV56516394; called by muse, mutect2, varscan2
- BTAF1 | c.3190A>C p.N1064H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99795261; called by muse, mutect2, varscan2
- BTBD11 | c.2915T>G p.I972S (on ENST00000280758 / NM_001018072.2; = p.I509S on NM_001017523.2) | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99775562; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTK | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.952); catalogued as rs1555977836, COSV100437565; called by muse, mutect2, varscan2
- BTN2A1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 21/309 reads (7%) | catalogued as COSV100438531; called by muse, mutect2
- BTN2A2 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100760372; called by muse, mutect2, varscan2
- BUB1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.27); catalogued as COSV100241217; called by muse, mutect2, varscan2
- BUB1B | c.2988C>A p.F996L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99806853; called by muse, mutect2, varscan2
- BVES | c.741A>C p.E247D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV100114897; called by muse, mutect2, varscan2
- C10orf120 | c.538C>A p.H180N | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61492312, COSV61492453; called by muse, mutect2, varscan2
- C10orf53 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100934876; called by muse, mutect2
- C10orf88 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64403572; called by muse, mutect2, varscan2
- C12orf4 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 66/866 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99712707; called by muse, mutect2
- C12orf4 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 60/218 reads (28%) | catalogued as COSV99712710; called by muse, mutect2, varscan2
- C12orf54 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100011594; called by muse, mutect2, varscan2
- C12orf56 | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100399348; called by muse, mutect2, varscan2
- C16orf71 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV100172912; called by muse, mutect2, varscan2
- C16orf87 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99587510; called by muse, varscan2
- C17orf75 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56752769, COSV99858633; called by muse, mutect2
- C17orf97 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs966859189, COSV100789313; called by muse, mutect2, varscan2
- C1D | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 68/293 reads (23%) | catalogued as rs754673476, COSV100878203, COSV63412999; called by muse, mutect2, varscan2
- C1GALT1C1L | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370033463; called by muse, mutect2, varscan2
- C1QC | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65889277; called by muse, mutect2, varscan2
- C1QL2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55606522, COSV55607948; called by muse, mutect2, varscan2
- C1R | c.402C>A p.F134L (on ENST00000536053 / NM_001354346.2; = p.F120L on NM_001733.7) | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56924379, COSV99864661; called by muse, mutect2, varscan2
- C2CD3 | c.2367T>G p.N789K | Missense Mutation (SNP) | VAF 204/659 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100486561; called by muse, varscan2
- C2CD6 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs370301019; called by muse, mutect2, varscan2
- C2orf16 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100820772; called by muse, mutect2, varscan2
- C2orf16 | c.3127C>A p.L1043I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs1254880586, COSV62678979; called by muse, mutect2, varscan2
- C2orf16 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs781639811, COSV100820773, COSV62676430; called by muse, mutect2, varscan2
- C2orf78 | c.2456C>A p.S819Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV101280958; called by muse, mutect2, varscan2
- C3 | c.4678G>A p.E1560K | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.111); catalogued as rs750498103, COSV99836547; called by muse, mutect2, varscan2
- C4A | c.3526A>C p.N1176H | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV101418332; called by muse, mutect2
- C4B | c.2579A>G p.D860G | Missense Mutation (SNP) | VAF 76/906 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV101426128; called by muse, mutect2
- C4orf50 | c.800T>C p.V267A (on ENST00000324058; = p.V1499A on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV60689788; called by muse, mutect2, varscan2
- C5AR2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as rs758673260, COSV57255706; called by muse, mutect2, varscan2
- C6 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 11/126 reads (9%) | catalogued as COSV54710507, COSV99667004; called by muse, mutect2
- C6orf58 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs766884453, COSV100314861; called by muse, mutect2, varscan2
- C6orf62 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 44/252 reads (17%) | catalogued as COSV100965865; called by muse, mutect2, varscan2
- C6orf89 | c.106G>T p.E36* (on ENST00000373685; = p.E43* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | catalogued as COSV100769721, COSV100769751; called by muse, mutect2, varscan2
- C6orf89 | c.958G>A p.D320N (on ENST00000373685; = p.D327N on NM_152734.4) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs79686273; called by muse, mutect2, varscan2
- C7orf26 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760205435, COSV100732892; called by muse, mutect2, varscan2
- C8orf34 | c.1289T>G p.I430R | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100298108; called by muse, mutect2, varscan2
- C9 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 145/599 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54675814; called by muse, mutect2, varscan2
- C9orf131 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100398083, COSV56611074; called by muse, mutect2, varscan2
- CA14 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529663; called by muse, mutect2, varscan2
- CA3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773052803, COSV99570671; called by mutect2, varscan2
- CABS1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as rs573726918, COSV56733628; called by muse, mutect2, varscan2
- CABYR | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV100510035; called by muse, mutect2, varscan2
- CACHD1 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV99262153; called by muse, mutect2
- CACHD1 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99261328; called by muse, mutect2, varscan2
- CACNA1A | c.4876C>A p.L1626M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100802265; called by muse, mutect2, varscan2
- CACNA1C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV59696193; called by muse, mutect2, varscan2
- CACNA1C | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100218328; called by muse, mutect2, varscan2
- CACNA1E | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100702318; called by muse, mutect2, varscan2
- CACNA1F | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782006249, COSV100544722, COSV59905550; called by muse, mutect2, varscan2
- CACNA1F | c.3367A>C p.I1123L | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.23); catalogued as COSV100544724; called by muse, mutect2, varscan2
- CACNA1F | c.1981C>A p.L661I | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100544725; called by muse, mutect2, varscan2
- CACNA1H | c.4735C>T p.R1579W | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373867411; called by muse, mutect2, varscan2
- CACNA1S | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs768968718, COSV100754957; called by muse, varscan2
- CACNB4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 13/129 reads (10%) | catalogued as rs1304491659, COSV52390979; called by muse, mutect2, varscan2
- CACNG2 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100268786; called by muse, mutect2, varscan2
- CACNG5 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 48/726 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.076); catalogued as COSV99400553; called by muse, mutect2
- CAD | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99254959; called by muse, mutect2, varscan2
- CAD | c.1913A>G p.Q638R | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV99254960; called by muse, mutect2, varscan2
- CADM3 | c.997A>G p.I333V (on ENST00000368125 / NM_001127173.3; = p.I367V on NM_021189.5) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100929902; called by muse, mutect2, varscan2
- CADPS2 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100462556; called by muse, varscan2
- CALCRL | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101130935; called by muse, mutect2, varscan2
- CALD1 | c.1978A>C p.S660R (on ENST00000361675 / NM_033138.4; = p.S405R on NM_004342.7) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100724196; called by muse, mutect2, varscan2
- CALD1 | c.2311G>T p.D771Y (on ENST00000361675 / NM_033138.4; = p.D516Y on NM_004342.7) | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724199; called by muse, mutect2, varscan2
- CALHM6 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | catalogued as COSV100889440; called by muse, mutect2, varscan2
- CAMKMT | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs759924384, COSV101034655; called by muse, mutect2, varscan2
- CAMLG | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777727; called by muse, mutect2, varscan2
- CAMSAP1 | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV100409804; called by muse, mutect2, varscan2
- CAMSAP3 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.852); catalogued as rs769934188, COSV50332957; called by muse, mutect2, varscan2
- CAND2 | c.931G>A p.D311N (on ENST00000456430 / NM_001162499.2; = p.D218N on NM_012298.3) | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs756369567, COSV99929029; called by muse, mutect2, varscan2
- CAPN2 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99688853; called by muse, mutect2, varscan2
- CAPN6 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 63/457 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100136851; called by muse, mutect2, varscan2
- CAPN6 | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100136853; called by muse, mutect2, varscan2
- CAPNS1 | c.759A>C p.Q253H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99497064; called by muse, mutect2, varscan2
- CAPRIN1 | c.216+1G>A p.X72_splice | Splice Site (SNP) | VAF 56/215 reads (26%) | catalogued as COSV100403814; called by muse, mutect2, varscan2
- CAPRIN2 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1402077640, COSV99195484; called by muse, mutect2, varscan2
- CARD8 | c.1605G>T p.Q535H (on ENST00000651546 / NM_001184900.3; = p.Q485H on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100751100; called by muse, mutect2, varscan2
- CARMIL1 | c.2981A>C p.K994T | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100277650; called by muse, mutect2, varscan2
- CARMIL2 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1336504683, COSV99537630; called by muse, varscan2
- CASD1 | c.1106A>C p.Q369P | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.266); catalogued as rs1253941819, COSV99802573; called by muse, mutect2, varscan2
- CASP5 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99507529; called by muse, mutect2, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, mutect2, varscan2
- CASP8AP2 | c.5510G>T p.R1837I | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs984365535, COSV99387013; called by muse, mutect2, varscan2
- CASS4 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs866071361, COSV100824666; called by muse, mutect2, varscan2
- CAT | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752948472, COSV99573064, COSV99573216; called by muse, mutect2, varscan2
- CATSPER1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150298490; called by muse, mutect2, varscan2
- CAV2 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV56063830, COSV99760773; called by muse, mutect2, varscan2
- CAV3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs773309037, COSV57479778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBFB | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs761036715, COSV51996734, COSV51999572, COSV52001985; called by muse, mutect2, varscan2
- CBLB | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV51420650, COSV51426325; called by muse, mutect2, varscan2
- CBLIF | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV99950931; called by muse, mutect2, varscan2
- CBLL2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs908529189, COSV100081687, COSV60368760; called by muse, mutect2, varscan2
- CBLN3 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99249656; called by muse, mutect2, varscan2
- CBX8 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV99485848; called by muse, mutect2, varscan2
- CCAR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308578865, COSV56274352; called by muse, varscan2
- CCAR1 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as COSV56270744, COSV99770764; called by muse, varscan2
- CCDC102B | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100103369; called by muse, mutect2, varscan2
- CCDC110 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 94/302 reads (31%) | catalogued as COSV56872519; called by muse, mutect2, varscan2
- CCDC110 | c.1531dup p.I511Nfs*3 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs755233311; called by mutect2, varscan2
- CCDC112 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101100434; called by muse, mutect2, varscan2
- CCDC114 | c.1130-1G>T p.X377_splice | Splice Site (SNP) | VAF 40/117 reads (34%) | catalogued as COSV100196698; called by muse, mutect2, varscan2
- CCDC148 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99320298; called by muse, mutect2, varscan2
- CCDC150 | c.2262T>C p.I754= | Splice Region (SNP) | VAF 46/140 reads (33%) | catalogued as rs1211355009, COSV99776864; called by muse, mutect2, varscan2
- CCDC157 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99306497; called by mutect2, varscan2
- CCDC158 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV101187230; called by muse, mutect2, varscan2
- CCDC158 | c.1794A>C p.E598D | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101187231; called by muse, mutect2, varscan2
- CCDC158 | c.1368G>T p.K456N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs949970281, COSV101187232, COSV66355493; called by muse, mutect2, varscan2
- CCDC160 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 29/235 reads (12%) | catalogued as COSV100892109; called by muse, mutect2, varscan2
- CCDC160 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100892110; called by muse, mutect2, varscan2
- CCDC160 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 129/292 reads (44%) | catalogued as COSV100892111; called by muse, mutect2, varscan2
- CCDC170 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as rs775579048, COSV53340928; called by muse, mutect2, varscan2
- CCDC170 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as rs370430081; called by muse, mutect2, varscan2
- CCDC170 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV53342826, COSV99498385; called by muse, mutect2, varscan2
- CCDC171 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99900548; called by muse, mutect2, varscan2
- CCDC171 | c.1077-1G>T p.X359_splice | Splice Site (SNP) | VAF 61/247 reads (25%) | catalogued as rs766740699, COSV99900550; called by muse, mutect2, varscan2
- CCDC174 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100358567; called by muse, mutect2, varscan2
- CCDC174 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100358568; called by muse, mutect2, varscan2
- CCDC178 | c.1263T>G p.F421L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV100284727; called by muse, mutect2, varscan2
- CCDC18 | c.1842G>T p.K614N (on ENST00000343253 / NM_001306076.1; = p.K615N on NM_206886.4) | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV58143177; called by muse, mutect2, varscan2
- CCDC186 | c.1455A>C p.E485D | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV100991106; called by muse, mutect2, varscan2
- CCDC39 | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 154/538 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV56490396, COSV99868585; called by muse, mutect2, varscan2
- CCDC54 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99660190; called by muse, mutect2
- CCDC58 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52246989; called by muse, mutect2, varscan2
- CCDC59 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 85/442 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99810655; called by muse, mutect2, varscan2
- CCDC7 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 38/456 reads (8%) | catalogued as COSV99511553; called by muse, mutect2
- CCDC73 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58795993; called by muse, varscan2
- CCDC81 | c.1766G>A p.R589K (on ENST00000445632 / NM_001156474.2; = p.R499K on NM_021827.4) | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99564274; called by muse, mutect2, varscan2
- CCDC88A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 81/307 reads (26%) | catalogued as COSV55061573; called by muse, mutect2, varscan2
- CCER1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100727021; called by muse, mutect2, varscan2
- CCL13 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV99861718; called by muse, mutect2, varscan2
- CCL18 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs540060026; called by muse, mutect2, varscan2
- CCL23 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs202213083; called by muse, mutect2, varscan2
- CCN1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV71704396; called by muse, mutect2, varscan2
- CCNB1IP1 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100738558; called by muse, mutect2, varscan2
- CCNB1IP1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV100738559; called by muse, mutect2, varscan2
- CCNB3 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99328939; called by muse, mutect2, varscan2
- CCNE1 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV99388370; called by muse, mutect2, varscan2
- CCNQ | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.724); catalogued as rs1557026096, COSV99367952; called by muse, mutect2
- CCNQ | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99367953; called by muse, mutect2, varscan2
- CCR1 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV99946696; called by muse, mutect2, varscan2
- CCR4 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100447380; called by muse, mutect2, varscan2
- CCSER1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 70/265 reads (26%) | catalogued as COSV100388549; called by muse, mutect2, varscan2
- CCSER2 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779512549, COSV99825874; called by muse, mutect2, varscan2
- CCT4 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771250995, COSV101075184; called by muse, mutect2, varscan2
- CCT8L2 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63462153, COSV63462489, COSV63462823; called by muse, varscan2
- CD101 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs199631117; called by muse, mutect2, varscan2
- CD109 | c.4102A>C p.N1368H | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99753467; called by muse, mutect2, varscan2
- CD109 | c.4235G>A p.G1412D | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99753470; called by muse, mutect2, varscan2
- CD163 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs868312071, COSV100775818; called by muse, mutect2, varscan2
- CD163 | c.1858C>A p.L620I | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV100775819, COSV104418153; called by muse, mutect2, varscan2
- CD180 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99842223; called by muse, mutect2, varscan2
- CD1C | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761108555, COSV63806922; called by mutect2, varscan2
- CD22 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99323153; called by muse, mutect2, varscan2
- CD22 | c.2190C>A p.F730L | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV99323154; called by muse, mutect2, varscan2
- CD244 | c.715G>A p.A239T (on ENST00000368033 / NM_001166663.2; = p.A234T on NM_016382.4) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs572370510, COSV59236914; called by mutect2, varscan2
- CD248 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs368694753, COSV60936659; called by muse, mutect2, varscan2
- CD274 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs897885359, COSV101055992; called by muse, mutect2, varscan2
- CD300LD | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100032415; called by muse, mutect2, varscan2
- CD4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163756; called by muse, mutect2, varscan2
- CD40LG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1350282799, COSV65699086; ClinVar: uncertain significance; called by muse, mutect2
- CD40LG | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776239740, COSV101033486; called by muse, varscan2
- CD63 | c.468A>C p.K156N | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99141767; called by muse, mutect2, varscan2
- CD8B | c.699G>T p.Q233H (on ENST00000331469 / NM_172213.4; = p.Q203H on NM_172102.4) | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV100514488; called by muse, mutect2, varscan2
- CDC14A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CDC14B | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99685637; called by muse, mutect2, varscan2
- CDC20B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1008892536, COSV57054773; called by muse, mutect2
- CDC27 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV99294782; called by muse, mutect2, varscan2
- CDC37L1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101116522; called by muse, varscan2
- CDC40 | c.1505T>G p.F502C | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs779945821, COSV57013478; called by muse, mutect2, varscan2
- CDH11 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV51756404, COSV99218170; called by muse, mutect2
- CDH11 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV51758880; called by muse, mutect2, varscan2
- CDH12 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.606); catalogued as COSV101202417, COSV66397283; called by muse, mutect2, varscan2
- CDH18 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434063547, COSV56927210, COSV99931214; called by muse, varscan2
- CDH2 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52285382, COSV99296721; called by muse, mutect2, varscan2
- CDH22 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV100952833; called by muse, mutect2, varscan2
- CDH6 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV99417950; called by mutect2, varscan2
- CDH7 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542242; called by muse, mutect2, varscan2
- CDH9 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV50257873; called by muse, varscan2
- CDH9 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99144122; called by muse, mutect2, varscan2
- CDHR3 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV100488277; called by muse, mutect2, varscan2
- CDK12 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000304; called by muse, mutect2
- CDK13 | c.4525G>A p.G1509R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV51703259, COSV99475467; called by muse, mutect2, varscan2
- CDK15 | c.632G>A p.G211D (on ENST00000652192 / NM_001366386.2; = p.G160D on NM_139158.2) | Missense Mutation (SNP) | VAF 116/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53639161, COSV99643096; called by muse, mutect2, varscan2
- CDK17 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99702692; called by muse, mutect2, varscan2
- CDK2 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99906719; called by muse, mutect2, varscan2
- CDK20 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100308066; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs764066941, COSV62578296; called by muse, mutect2, varscan2
- CDK6 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as rs761377867, COSV56008615; called by muse, mutect2, varscan2
- CDKL1 | c.868A>C p.N290H | Missense Mutation (SNP) | VAF 267/825 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV99367419; called by muse, mutect2, varscan2
- CDKL2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs755711267, COSV56733569; called by muse, mutect2, varscan2
- CDKL2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276900; called by muse, mutect2
- CDKL3 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99527826; called by muse, mutect2
- CDKL3 | c.684T>A p.F228L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99527831; called by muse, varscan2
- CDKL4 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 162/564 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV101115262; called by muse, mutect2, varscan2
- CDKL5 | c.1835C>A p.S612Y | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV101184286; called by muse, mutect2, varscan2
- CDON | c.2586T>G p.F862L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99701261; called by muse, mutect2, varscan2
- CDON | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV99701263; called by muse, mutect2, varscan2
- CDRT1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 58/591 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs761413180; called by muse, mutect2
- CEACAM18 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101140335; called by muse, mutect2, varscan2
- CEACAM4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs201492288, COSV55731164; called by muse, mutect2, varscan2
- CEACAM8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV99747375, COSV99747595; called by muse, mutect2
- CEBPE | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs200138272; called by muse, mutect2, varscan2
- CELSR2 | c.2705G>A p.R902H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1446038037, COSV54775168; called by muse, mutect2, varscan2
4,921 further variants in this file (3,672 protein-altering or splice-affecting, 1,138 silent, 111 other) are not listed here.
